Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012424-03A.1 (aliquot TARGET-15-SJMPAL012424-03A.1-01D) from TARGET case TARGET-15-SJMPAL012424, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,050 days).
Specimen TARGET-15-SJMPAL012424-03A.1: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfccf472-b47b-4418-ae0e-afa4de39ab5e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012424-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012424-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/356e5925-4fb4-478b-b16c-7ee25b2ef749

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAB38 | c.614G>T p.C205F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV54713811; called by muse, mutect2
- SVEP1 | c.3196C>T p.L1066F | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1409338019; called by muse, mutect2, varscan2
- C18orf63 | c.1437C>A p.D479E | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2
- GRIA4 | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- PGBD1 | c.1414C>A p.H472N | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- PTHLH | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.203); called by muse, mutect2
- ZNF486 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- RBM4 | c.156A>C p.I52= | Silent (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- RIT2 | c.486C>T p.T162= | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV100449498; called by muse, mutect2, varscan2
- TFAP2B | c.441G>A p.P147= | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2
- CSGALNACT1 | c.*90A>T | 3'UTR (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- PDE10A | c.106+91775G>A | Intron (SNP) | VAF 50/90 reads (56%) | catalogued as rs570360405; called by muse, mutect2, varscan2
